Somatic mutation profile of tumor specimen TCGA-EU-5906-01A (aliquot TCGA-EU-5906-01A-11D-1669-08) from TCGA case TCGA-EU-5906, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.4 years (20,246 days).
Specimen TCGA-EU-5906-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcb8edbc-80b3-46d8-bcd4-461d2222462a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EU-5906-10A (Blood Derived Normal), aliquot TCGA-EU-5906-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d648caf-94a4-4bab-b566-02bc7ed452af

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 43, Silent 15, Frame Shift Del 7, Nonsense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1721C>G p.P574R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61282949; called by muse, mutect2, varscan2
- ADAMTS2 | c.2374G>A p.G792S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52397094; called by muse, mutect2, varscan2
- AKAP12 | c.1864C>A p.R622S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53583621; called by muse, mutect2, varscan2
- ALDH3B1 | c.839C>G p.P280R | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); catalogued as COSV50292018; called by muse, mutect2, varscan2
- ANK3 | c.5407T>C p.S1803P | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs748336491, COSV55086013; called by muse, mutect2, varscan2
- BAAT | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.132); catalogued as COSV52291296; called by muse, mutect2, varscan2
- CDC40 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.956); catalogued as COSV55621719; called by muse, mutect2, varscan2
- COA6 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as COSV64017077; called by muse, mutect2, varscan2
- CSNK1A1 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55798983; called by muse, mutect2, varscan2
- CTH | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as rs147044875; called by muse, mutect2, varscan2
- CYP2E1 | c.959A>C p.E320A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV53315784; called by muse, mutect2, varscan2
- DDX24 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 41/199 reads (21%) | catalogued as COSV58213960; called by muse, mutect2, varscan2
- DUSP7 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as COSV56589902; called by muse, mutect2
- ERBIN | c.3337G>A p.A1113T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV52328853; called by muse, mutect2
- FANCM | c.2021T>C p.L674P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV57507570; called by muse, mutect2, varscan2
- GFOD1 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64955523; called by muse, mutect2, varscan2
- GOLGA3 | c.3691C>A p.Q1231K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV52645790; called by muse, mutect2, varscan2
- HCAR2 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61025992; called by muse, mutect2, varscan2
- INTS1 | c.3346G>T p.V1116L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.591); catalogued as COSV67180165; called by muse, mutect2, varscan2
- LYSMD4 | c.323A>C p.Q108P (on ENST00000409796 / NM_001284417.2; = p.Q109P on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60387840; called by muse, mutect2, varscan2
- MAP1S | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60724951; called by muse, mutect2, varscan2
- MYO18A | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV62874748; called by muse, mutect2, varscan2
- NCAPH2 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV52689649; called by muse, mutect2, varscan2
- NFATC4 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.694); catalogued as COSV51609229, COSV51613308; called by muse, mutect2, varscan2
- NLRP5 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs370513314; called by muse, mutect2
- NRIP1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59660892; called by muse, mutect2
- NUDCD1 | c.79_80del p.L27* | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs769155389; called by pindel, varscan2
- NUP98 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61439701; called by muse, mutect2, varscan2
- P2RX3 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV54445192; called by muse, mutect2, varscan2
- PI4KA | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55425491; called by muse, mutect2, varscan2
- PIGT | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.015); catalogued as rs551062552, COSV54126255, COSV54128901; called by muse, mutect2
- POLQ | c.3232T>A p.C1078S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.053); catalogued as COSV51763146; called by muse, mutect2, varscan2
- PSMC1 | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54322332; called by muse, mutect2, varscan2
- SERINC5 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV72597496; called by muse, mutect2, varscan2
- SLC36A1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1245578463, COSV54656885, COSV99695774; called by muse, mutect2, varscan2
- SPINK2 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50534661; called by muse, mutect2, varscan2
- STRBP | c.1796C>A p.A599D | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV62120727; called by muse, mutect2
- TEC | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV67406704; called by muse, mutect2, varscan2
- TTN | c.82410C>G p.D27470E (on ENST00000591111; = p.D20046E on NM_003319.4) | Missense Mutation (SNP) | VAF 55/230 reads (24%) | PolyPhen probably damaging (0.998); catalogued as COSV60021351, COSV60397722; called by muse, mutect2, varscan2
- TTN | c.66701C>A p.T22234N (on ENST00000591111; = p.T14810N on NM_003319.4) | Missense Mutation (SNP) | VAF 88/353 reads (25%) | PolyPhen benign (0.003); catalogued as rs771783837, COSV60397758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA1A | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as COSV55499103; called by muse, mutect2, varscan2
- UBQLN1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV57409747; called by muse, mutect2, varscan2
- VHL | c.568del p.D190Tfs*12 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as COSV56549420, COSV56565951; called by mutect2, pindel*, varscan2
- ZEB2 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV100355938, COSV57967746; called by muse, mutect2, varscan2
- ZGLP1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs1330009133, COSV58534125; called by muse, mutect2, varscan2
- ZNF479 | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV58641712; called by muse, mutect2
- ZNF808 | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 31/131 reads (24%) | catalogued as COSV63121989; called by muse, mutect2, varscan2
- ANKIB1 | c.2398_2399del p.I800Sfs*30 | Frame Shift Del (DEL) | VAF 96/381 reads (25%) | called by pindel, varscan2
- CCN4 | c.540_541del p.C180* | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by pindel, varscan2
- EPHB3 | c.2582_2593del p.M861_P864del | In Frame Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- LCMT2 | c.1913_1916del p.L638Cfs*39 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- RSC1A1 | c.845del p.L282* | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- STYXL2 | c.3394del p.M1132Wfs*? (on ENST00000271385; = p.M1132Wfs*33 on NM_001080426.3) | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- TRBV6-1 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADSL | c.30C>G p.P10= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53410936; called by mutect2, varscan2
- C8A | c.966A>T p.P322= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV63486806; called by muse, mutect2, varscan2
- CUL3 | c.2112A>G p.E704= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs765838987, COSV52371491; called by muse, mutect2, varscan2
- ESPL1 | c.5592C>G p.T1864= | Silent (SNP) | VAF 59/285 reads (21%) | catalogued as COSV54477296; called by muse, mutect2, varscan2
- FILIP1L | c.1824T>C p.N608= (on ENST00000354552 / NM_182909.3; = p.N368= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/211 reads (19%) | catalogued as COSV100496611, COSV58777314; called by muse, mutect2, varscan2
- GABRG1 | c.1293G>A p.R431= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV54951642, COSV54962925; called by muse, mutect2, varscan2
- HCAR2 | c.196C>T p.L66= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV61026015; called by muse, mutect2, varscan2
- MAP4K4 | c.2484C>G p.T828= (on ENST00000347699 / NM_001242559.2; = p.T746= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV56342100; called by muse, mutect2
- NOL8 | c.3216C>G p.V1072= | Silent (SNP) | VAF 55/278 reads (20%) | catalogued as COSV62638360; called by muse, mutect2, varscan2
- OXSM | c.1275T>G p.V425= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV55002881; called by muse, mutect2, varscan2
- PRRC2C | c.7827T>A p.P2609= (on ENST00000367742; = p.P2607= on NM_015172.4) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58914909; called by muse, mutect2, varscan2
- SCAI | c.423A>C p.T141= (on ENST00000336505 / NM_001144877.3; = p.T164= on NM_173690.5) | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV60618883; called by muse, mutect2, varscan2
- SF3A1 | c.633A>T p.L211= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as COSV53171671; called by muse, mutect2, varscan2
- TOP3A | c.1077C>T p.Y359= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV58181522; called by muse, mutect2
- UBE2D1 | c.204T>A p.A68= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV64219037; called by muse, mutect2, varscan2
